Surgical pathology report (de-identified scan), TCGA case TCGA-EL-A3CU, project TCGA-THCA (Thyroid Carcinoma), tissue source site MD Anderson, specimen TCGA-EL-A3CU-01A (Primary Tumor).

UUID: 2ED57CDC-E420-4895-ASA9-F62480DBBE1E

**ry Case
gy Report**
Pathology,

DOB: _____ Sex: F
Physician: _____

Received: _____ Pathologist: _____ Accession: _____
Case type: Surgical History

**** Case imported from legacy computer system. The format of this report does not match the original case. ****
**** For cases prior to _____, the section "SPECIMEN" may have been added. ****

DIAGNOSIS

- (A) RIGHT MID JUGULAR LYMPH NODE:
Lymph node, no tumor.
- (B) RIGHT UPPER POLE NODULE:
Lymph node, no tumor.
- (C) RIGHT INFERIOR PARATHYROID:
Vessel and lymphoid tissue, no parathyroid tissue present.
- (D) TOTAL THYROIDECTOMY:
PAPILLARY CARCINOMA OF THYROID MEASURES (1.5 CM), TUMOR CLOSE TO
RESECTION MARGIN, TUMOR AT LESS THAN 1.0 MM FROM MARGIN OF
RESECTION.
METASTATIC PAPILLARY CARCINOMA OF THYROID IN 4 OF 5 REGIONAL
LYMPH NODES.
Parathyroid gland, no tumor.

ICD-0-3
Carcinoma, papillary, thyroid
8260/3
Site: thyroid, NOS C73.9

Entire report and diagnosis completed by:
Report released by:

h
10/15/11

GROSS DESCRIPTION

- (A) RIGHT MID JUGULAR LYMPH NODE - A single lymph node, (0.3 x 0.2 x 0.2 cm). Submitted entirely for frozen section diagnosis in A.
*FS/DX: ONE LYMPH NODE, NO TUMOR PRESENT.
- (B) RIGHT UPPER POLE NODULE - One fragment of tan soft tissue (0.5 x 0.4 x 0.3 cm). Submitted in toto for frozen section diagnosis in B.
*FS/DX: ONE LYMPH NODE, NO TUMOR PRESENT.
- (C) RIGHT INFERIOR PARATHYROID - Two tissue fragments, (0.2 and 0.6 cm in greatest dimension). Specimen is entirely submitted for frozen section diagnosis in C.
*FS/DX: VESSEL AND LYMPHOID TISSUE.
- (D) TOTAL THYROIDECTOMY - The product of overall thyroidectomy with overall measurement of 7.0 x 4.0 x 1.5 cm. The right lobe is larger than the left lobe and contain a light tan and firm nodule on the lateral right aspect of the specimen. The tumor measures 1.5 x 1.0 x 1.0 cm. Tumor abutting grossly the margin of resection. The specimen is submitted as follows:
SECTION CODE: D1, D2, representative section of the left lobe; D3-D10, sequential sectioning of the right lobe and the tumor from superior to inferior. Additional tissue is received with the main specimen, which consists of two fragments of soft tissue (0.5 and 1.5 cm in greatest dimension). Submitted in toto in D11.

SNOMED CODES

Source: NCI Genomic Data Commons file e8d0c138-5a41-476d-af06-4e217cd742f6 (TCGA-EL-A3CU.2ED57CDC-E420-4895-A5A9-F62480DBBE1E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).